Surgical pathology report (de-identified scan), TCGA case TCGA-97-8172, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-8172-01A (Primary Tumor).

[page 1 of 9]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. LUNG, RIGHT UPPER LOBE
2. STATION 10 LYMPH NODE
3. STATION 11 LYMPH NODE
4. STATION 2 AND 4 LYMPH NODE
5. STATION 7 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE: LOBECTOMY

- **ADENOCARCINOMA, ACINAR PREDOMINANT (3.5 CM), SEE NOTE.**
- **THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.**
- **SEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).**

Note: The tumor consists of acinar (90%) and lepidic (10%) components and has prominent extracellular mucin. An elastic stain is indefinite for visceral pleural invasion and a mucin stain is non-contributory. Results of mutational studies will be reported in addenda.

2. LYMPH NODE, LEVEL 10: BIOPSY

- **FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5).**

3. LYMPH NODE, LEVEL 11: BIOPSY

- **FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5).**

4. LYMPH NODE, LEVELS 2 AND 4: BIOPSIES

- **NINE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/9).**

5. LYMPH NODE, LEVEL 7: BIOPSY

- **SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6).**

[page 2 of 9]
Specimens: 1: LUNG, RIGHT UPPER LOBE
2: STATION 10 LYMPH NODE
3: STATION 11 LYMPH NODE
4: STATION 2 AND 4 LYMPH NODE
5: STATION 7 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: Lung

Procedure: Lobectomy

Specimen Integrity: Intact

Specimen Laterality: Right

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

3.5cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

**Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by
invasive carcinoma**

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

**pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest
dimension surrounded by lung or visceral pleura without
bronchoscopic evidence of invasion more proximal than the lobar
bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less
in greatest dimension with any of the following features of extent:
involves main bronchus, 2 cm or more distal to the carina; invades
the visceral pleura; associated with atelectasis or obstructive
pneumonitis that extends to the hilar region but does not involve the
entire lung**

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

32

Number Involved

0

Distant Metastases (pM): Not applicable

[page 3 of 9]
[REDACTED]
Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

[REDACTED] with hx of breast cancer, now with a RUL adenocarcinoma.

MACROSCOPIC DESCRIPTION:

The specimen is received in five parts, each labeled with the patient's name.

1. Part one is labeled 'lung, right upper lobe'. It consists of a right lobe of lung, measuring 15.5 x 10.5 x 4 cm. The two staple lines measures 6 cm and 5.5 cm which is shaved and the pleura around the staple line is inked in black. The bronchial margin at the hilum area measures 2 cm and the vascular margin measures 1.2 cm. The pleura are gray pink glistening and mottled moderately with fine black streaks. There is a puckered area measuring 2.5 cm in greatest dimension. Beneath the puckered area there is a gray white firm nodule with ill defined borders measuring 3.5 x 3 x 2 cm, located 3 cm from the bronchial resection margin, and 2 cm from the closest staple line margin. The remainder of the parenchyma is red and blotchy. No other nodule grossly identified. Multiple anthracotic firm lymph nodes ranging from 0.3 cm to 0.6 cm identified from the hilar and peribronchial area. Representative sections are submitted.

2. Part two is labeled 'station 10 lymph node'. It consists of multiple soft red-black lymph nodes measuring 2.4 x 2 x 0.5 cm in aggregate. Entirely submitted in one cassette.

3. Part three is labeled 'station 11 lymph node '. It consists of multiple soft red-black lymph nodes measuring 2 x 1.7 x 0.6 cm in aggregate. Entirely submitted in one cassette.

4. Part four is labeled 'station 2 and 4 lymph node'. It consists of multiple soft red-black lymph nodes measuring 0.5 cm to 0.8 cm. Entirely submitted in three cassettes.

5. Part five is labeled 'station 7 lymph node '. It consists of multiple soft red-black lymph nodes measuring 2.4 x 1.5 x 0.5 cm in aggregate. Entirely submitted in one cassette.

[REDACTED]

[page 4 of 9]
SUMMARY OF SECTIONS:

1A-1E nodule
1F staple line margin
1G bronchial margin, shaved
1H vascular margin, shaved
1I anthracotic lymph node
1J random section
2A entirely submitted
3A entirely submitted
4A-4C entirely submitted
5A entirely submitted

SPECIAL PROCEDURES:

Elastic

Final Diagnosis performed by

[REDACTED]

Electronically [REDACTED]

ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK were sent on [REDACTED] for patient [REDACTED]
[REDACTED] The test is to be performed on tissue from case [REDACTED]
[REDACTED] The case report, slides, and blocks for the cited
accession number were retrieved from archives. The pathologist whose
signature appears below reviewed the original pathology report,
examined candidate H&E slides, and selected block 1B appropriate to
the specifications of the ordered molecular analysis. x1 H&E and x9
unstained slides were prepared and forwarded to [REDACTED] where the
subject molecular test will be performed. An addendum report will be
issued when the results of this molecular test are available.

Addendum #1 performed by

[REDACTED]

Electronically signed [REDACTED]

[page 5 of 9]
ADDENDUM #2:

MOLECULAR ONCOLOGY

KRAS MUTATION ANALYSIS

Referring Physician: [REDACTED]

Body Site: Right upper lobe of lung

Specimen Type: Slides

Clinical Data: Adenocarcinoma

RESULTS: Positive for a p.G12V (c.35G>T) mutation in codon 12 of the KRAS gene.

INTERPRETATION:

Mutations in the KRAS gene are reported to correlate with poor prognosis and resistance to tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer.

COMMENT:

KRAS mutations occur in 15-30% of non-small-cell lung cancer (NSCLC) patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified

[page 6 of 9]
and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED]

Date: [REDACTED]

[REDACTED]

Addendum #2 performed by

[REDACTED]

Electronically signed

[REDACTED]

ADDENDUM #3:

[page 7 of 9]
EGFR Mutation Analysis

[REDACTED]

Referring Physician: [REDACTED]

Body Site: Right upper lobe of lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 4% tumor cellularity upon pathologist review

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

[page 8 of 9]
METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

[REDACTED]

DISCLAIMER:

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigation or for research. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[REDACTED]

Electronically signed by: [REDACTED]

Date: [REDACTED]

[REDACTED]

[page 9 of 9]
Addendum #3 performed by

[REDACTED]

Electronically signed

[REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED].

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file c22c8cf2-9952-4ac0-8880-ac336c5ed27a (TCGA-97-8172.EF65FDD5-820A-4029-A667-56B5200276A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).